Gene-level copy-number profile of tumor specimen C3L-05261-03 (profiled together with C3L-05261-04) from CPTAC case C3L-05261, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 40.5 years (14,788 days).
Specimen C3L-05261-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d6ebdf4d-67e4-447e-9858-ec2bef62a856.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-05261-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,717 have no estimate.
https://portal.gdc.cancer.gov/files/d303aa9e-050e-479d-b0c0-4b05f2e3e4d0

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 513; copy number 1: 10; copy number 2: 10,742; copy number 3: 25,777; copy number 4: 17,739; copy number 5: 3,247; copy number 6: 236; copy number 7: 347; copy number 8: 248; copy number 9: 47.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:20,243,095–20,244,664, 1 gene: LINC01757.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 642 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:147,242,654–153,693,992, 310 genes, copy number 7–8 (within-gene range 6–8) (broad region; genes not listed).
- chr1:153,726,252–158,470,857, 228 genes, copy number 7–8 (broad region; genes not listed).
- chr1:173,714,941–174,160,165, 17 genes, copy number 8 (within-gene range 4–8): KLHL20, BX248409.1, RN7SKP160, CENPL, Y_RNA, DARS2, GAS5, GAS5-AS1, ZBTB37, SERPINC1, RNA5SP67, RC3H1, RNA5SP68, RC3H1-IT1, LINC02776, RPL30P1, RABGAP1L-DT.
- chr1:182,407,621–185,291,781, 61 genes, copy number 7–9 (within-gene range 6–9) (broad region; genes not listed).
- chr1:191,823,432–192,957,713, 9 genes, copy number 7 (within-gene range 3–7): LINC02770, AL359081.1, RGS18, AL390957.1, AL513175.1, AL513175.2, RGS21, AL136987.1, RGS1.
- chr1:194,188,967–194,719,236, 4 genes, copy number 7: EEF1A1P14, AL513348.1, RNU6-983P, AL353072.1.
- chr21:26,158,091–27,143,949, 13 genes, copy number 7 (within-gene range 5–7): AP001439.1, AP000229.1, RNU6-926P, AP001595.1, AP001596.1, CYYR1-AS1, AP001596.2, CYYR1, ADAMTS1, AP001599.1, ADAMTS5, MIR4759, GPX1P2.

Autosomal genes at a single copy (total copy number 1): 10. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
